CCDI case PBCPNG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/055c3a56-958f-4a23-a83e-dc17417a0966

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.7 years (243 days).

Biospecimens (2 samples)
- Sample 0DWWME: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWWMU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
